Somatic mutation profile of tumor specimen TARGET-30-PAKJRE-01A (aliquot TARGET-30-PAKJRE-01A-01W) from TARGET case TARGET-30-PAKJRE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.0 years (1,100 days).
Specimen TARGET-30-PAKJRE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec389157-168a-49dd-89e2-6bf37d15a59b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKJRE-10A (Blood Derived Normal), aliquot TARGET-30-PAKJRE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bfbc6cc-8177-4cd0-9bc4-30b0dca2ddb3

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.10432G>T p.V3478F | Missense Mutation (SNP) | VAF 100/574 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV71283487; called by muse, mutect2, varscan2
- ADAM28 | c.822G>C p.E274D | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.762); catalogued as COSV56099330, COSV56100596; called by muse, mutect2
- APOB | c.12602G>T p.R4201I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV51923703, COSV51937998; called by muse, mutect2, varscan2
- CHRM5 | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV67246762; called by muse, mutect2
- EIF3A | c.3958C>G p.R1320G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs192094747, COSV60775024; called by mutect2, varscan2
- EPHX1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV55298781; called by muse, mutect2, varscan2
- FAM47C | c.2332C>A p.L778I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV63723756; called by muse, mutect2, varscan2
- FUOM | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775043157, COSV53369215; called by muse, mutect2, varscan2
- HMCN1 | c.7734T>A p.S2578R | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV54878221; called by muse, mutect2, varscan2
- ISM1 | c.881C>A p.T294K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV52602590; called by muse, mutect2, varscan2
- ITGA8 | c.661A>C p.S221R | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65224730; called by muse, mutect2, varscan2
- KCNS2 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs1280458788; called by muse, mutect2, varscan2
- LAMA3 | c.7195G>C p.V2399L (on ENST00000313654 / NM_198129.4; = p.V790L on NM_000227.6) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV52529950; called by muse, mutect2, varscan2
- LAYN | c.613C>A p.L205M (on ENST00000375615 / NM_001258390.1; = p.L197M on NM_178834.5) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV65104379; called by muse, mutect2, varscan2
- MCOLN2 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1406991148, COSV99394184; called by muse, mutect2
- MMP27 | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52779779; called by muse, mutect2, varscan2
- MTIF3 | c.641T>A p.L214H | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773201911, COSV63528461; called by muse, mutect2, varscan2
- NECAP2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.491); catalogued as COSV61432921; called by muse, mutect2, varscan2
- OSBPL8 | c.1050T>A p.S350R | Missense Mutation (SNP) | VAF 92/518 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as COSV53878204; called by muse, mutect2, varscan2
- PMEL | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); catalogued as COSV59384214; called by muse, mutect2, varscan2
- POLI | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54187749; called by muse, mutect2, varscan2
- PTPN11 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 90/753 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100691990; called by muse, mutect2, varscan2
- RIPK3 | c.581T>A p.V194E | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53474207; called by muse, mutect2, varscan2
- SLC9A4 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV54829135, COSV54839520; called by muse, mutect2
- STOX2 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs367958453; called by muse, mutect2, varscan2
- WDR44 | c.2499G>C p.W833C | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54160293, COSV54160398; called by muse, mutect2, varscan2
- ZCCHC4 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 107/624 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs779638177, COSV57180294; called by muse, mutect2, varscan2
- CACHD1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 32/734 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2
- CRPPA | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFCAB6 | c.3265G>T p.V1089L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.08); called by muse, mutect2
- MED17 | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- NAV3 | c.3414G>T p.L1138F | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POM121L12 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- ACACB | c.171A>C p.T57= | Silent (SNP) | VAF 35/293 reads (12%) | catalogued as COSV58128313; called by muse, mutect2, varscan2
- ARRB2 | c.216G>T p.L72= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as COSV52616497; called by muse, mutect2, varscan2
- IL12B | c.393C>T p.C131= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs757355295, COSV51454192; called by muse, mutect2, varscan2
- KCNS2 | c.1212G>T p.L404= | Silent (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- KIAA1109 | c.9861T>C p.N3287= | Silent (SNP) | VAF 266/676 reads (39%) | catalogued as COSV52662719; called by muse, varscan2
- KRTAP19-4 | c.180A>C p.S60= | Silent (SNP) | VAF 17/356 reads (5%) | called by muse, mutect2
- MUSK | c.1635A>G p.L545= | Silent (SNP) | VAF 112/437 reads (26%) | catalogued as COSV51878409; called by muse, mutect2, varscan2
- PSMG3 | c.168C>T p.D56= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs144724087; called by muse, mutect2
- RABGEF1 | c.1017C>A p.G339= (on ENST00000439720 / NM_001287061.2; = p.G326= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV53160729; called by muse, mutect2, varscan2
- UGT8 | c.1149T>C p.H383= | Silent (SNP) | VAF 101/549 reads (18%) | catalogued as COSV60416429; called by muse, mutect2, varscan2
- NR4A3 | c.1254+146C>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
